Gene-level copy-number profile of tumor specimen TCGA-AG-A02X-01A from TCGA case TCGA-AG-A02X, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectum, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 77.8 years (28,399 days).
Specimen TCGA-AG-A02X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.7175eedf-4230-4c98-8abb-9022721484b6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-A02X-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dfd1d8e4-cc26-4bbd-aa77-72140acaafa3

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 185; copy number 1: 3,082; copy number 2: 22,710; copy number 3: 31,026; copy number 4: 1,858; copy number 6: 6; copy number 8: 710; copy number 9: 33; copy number 12: 125; copy number 13: 43; copy number 44: 33; copy number 55: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AG-A02X-01A-01D-A008-01): tumor purity 0.87, ploidy 2.67, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 175 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:22,719,517–22,719,598, 1 gene: MIR4684.
- chr1:43,933,320–43,991,170, 8 genes: ARTN, AL357079.1, AL357079.3, IPO13, AL357079.2, DPH2, ATP6V0B, B4GALT2.
- chr1:47,416,285–47,440,691, 3 genes: FOXE3, FOXD2-AS1, FOXD2.
- chr1:65,057,755–65,058,508, 2 genes: MIR3671, MIR101-1.
- chr1:100,538,139–100,542,021, 1 gene: GPR88.
- chr1:109,504,178–109,509,738, 1 gene: AMIGO1.
- chr1:119,619,377–119,648,266, 1 gene: ZNF697.
- chr1:179,035,309–179,035,652, 1 gene: AL139132.1.
- chr2:236,194,872–236,264,409, 2 genes (within-gene range 0–3): ASB18, RNU1-31P.
- chr3:71,675,414–71,756,496, 2 genes (within-gene range 0–3): EIF4E3, GPR27.
- chr5:73,444,827–73,453,395, 3 genes: FOXD1, FOXD1-AS1, LINC01385.
- chr5:179,550,554–179,634,784, 5 genes (within-gene range 0–2): RUFY1, PRDX2P3, RUFY1-AS1, HNRNPH1, Metazoa_SRP.
- chr7:19,112,474–19,121,916, 2 genes: AC003986.2, AC003986.3.
- chr7:149,422,675–149,497,817, 3 genes: AC073314.1, ZNF777, ZNF746.
- chr8:73,972,437–73,984,883, 3 genes: TMEM70, RPS20P21, DSTNP3.
- chr8:79,762,371–79,802,842, 2 genes (within-gene range 0–2): HEY1, LINC01607.
- chr9:91,409,045–91,427,144, 2 genes (within-gene range 0–3): NFIL3, AL353764.1.
- chr9:98,731,329–98,807,564, 2 genes: ANKS6, AL807776.1.
- chr11:23,403,805–23,419,190, 2 genes: WIZP1, MIR8054.
- chr11:74,738,478–74,746,114, 2 genes: AP001324.2, AP001324.1.
- chr11:130,002,938–130,041,071, 4 genes: LINC00167, AP003041.1, ELOBP2, AP003041.2.
- chr12:2,048,352–2,049,463, 1 gene: CACNA1C-IT2.
- chr12:94,140,077–94,141,337, 1 gene: AC123567.1.
- chr12:120,904,702–120,915,123, 2 genes: AC069214.1, CLIC1P1.
- chr13:53,193,667–53,202,753, 2 genes: AL136359.1, PCDH8P1.
- chr15:101,495,052–101,495,567, 1 gene: AC090164.2.
- chr16:58,197,112–58,217,805, 2 genes (within-gene range 0–3): AC009107.1, RN7SL645P.
- chr17:142,789–191,587, 2 genes: DOC2B, LINC02091.
- chr17:32,258,615–32,265,404, 1 gene: AC026620.2.
- chr17:46,193,576–46,268,694, 5 genes: KANSL1-AS1, Y_RNA, MAPK8IP1P1, AC005829.2, AC005829.1.
- chr17:72,642,731–72,644,490, 1 gene: AC080037.2.
- chr17:79,778,148–79,850,110, 6 genes: CBX2, CBX8, AC100791.2, LINC01977, CBX4, AC100791.1.
- chr18:4,459,230–4,459,458, 1 gene: ELOCP27.
- chr18:8,688,022–8,707,621, 2 genes: TOMM20P3, GACAT2.
- chr18:57,136,322–57,150,410, 2 genes: AC100775.1, BOD1L2.
- chr18:76,491,629–76,498,088, 2 genes: AC018413.1, ZNF516-DT.
- chr19:35,248,330–35,279,821, 4 genes (within-gene range 0–3): LSR, AC002128.2, AC002128.1, USF2.
- chr20:3,777,504–3,806,121, 3 genes (within-gene range 0–4): SPEF1, CENPB, CDC25B.
- chr22:17,116,297–17,132,104, 2 genes (within-gene range 0–3): TMEM121B, LINC01664.
- chr22:49,817,248–50,801,309, 63 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 945 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,895,970, 710 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr8:39,106,990–39,284,917, 1 gene, copy number 55 (within-gene range 3–55): ADAM32.
- chr8:125,648,327–126,008,930, 1 gene, copy number 44 (within-gene range 2–44): AC016074.2.
- chr8:125,859,721–127,742,951, 29 genes, copy number 44: LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, AC018714.2, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, AC108925.1, CASC11, MYC.
- chr8:127,795,962–127,948,723, 3 genes, copy number 44: MIR1204, AC084123.1, TMEM75.
- chr13:18,467,172–22,916,369, 125 genes, copy number 12 (broad region; genes not listed).
- chr13:27,236,282–29,505,947, 43 genes, copy number 13 (within-gene range 3–13): LINC00412, RPL21, SNORD102, SNORA27, RASL11A, RNU6-70P, LINC01079, RNY1P1, GTF3A, MTIF3, RNU6-63P, LNX2, POLR1D, AL136439.1, NPM1P4, GSX1, PLUT, RNU6-73P, PDX1, ATP5F1EP2, LINC00543, CDX2, URAD, RN7SL272P, FLT3, KATNBL1P1, CHCHD2P8, PAN3-AS1, PAN3, EEF1A1P3, RNU6-82P, FLT1, AL139005.1, EIF4A1P7, Y_RNA, POMP, SLC46A3, RNU6-53P, CYP51A1P2, AL359741.1, POM121L13P, MTUS2, MTUS2-AS2.
- chr19:4,444,999–4,457,794, 1 gene, copy number 9 (within-gene range 3–9): UBXN6.
- chr19:4,454,014–5,456,856, 32 genes, copy number 9: AC011498.6, AC011498.1, HDGFL2, PLIN4, PLIN5, AC011498.4, LRG1, SEMA6B, AC011498.5, TNFAIP8L1, MYDGF, AC005339.1, DPP9, DPP9-AS1, AC005594.1, MIR7-3HG, MIR7-3, AC005523.1, FEM1A, AC005523.2, TICAM1, AC027319.1, PLIN3, ARRDC5, UHRF1, MIR4747, KDM4B, PTPRS, AC022517.1, RPL32P34, AC005790.1, ZNRF4.

Autosomal genes at a single copy (total copy number 1): 1,332. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
